Somatic mutation profile of tumor specimen TCGA-WX-AA44-01A (aliquot TCGA-WX-AA44-01A-11D-A38X-10) from TCGA case TCGA-WX-AA44, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 64.8 years (23,654 days).
Specimen TCGA-WX-AA44-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) db046f67-823a-4016-9538-f5a2358b3950.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WX-AA44-10A (Blood Derived Normal), aliquot TCGA-WX-AA44-10A-01D-A38X-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f9aa3ae7-3e34-4ddf-bd67-8c1b642d52aa

The open-access MAF lists 86 somatic variants for this specimen: 63 protein-altering or splice-affecting, 23 silent.
By variant classification: Missense Mutation 56, Silent 23, Frame Shift Del 2, Nonsense Mutation 2, Splice Site 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.920-2A>G p.X307_splice | Splice Site (SNP) | VAF 39/77 reads (51%) | hotspot (GDC flag); catalogued as rs397516439, COSV52693974, COSV52706655, COSV52945558, COSV53066011; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.11102A>G p.N3701S | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.084); catalogued as rs759344761, COSV101447269; called by muse, mutect2, varscan2
- ABCG5 | c.1757C>G p.T586S | Missense Mutation (SNP) | VAF 51/193 reads (26%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as COSV99571632; called by muse, mutect2, varscan2
- AMPD2 | c.2296T>A p.Y766N | Missense Mutation (SNP) | VAF 57/222 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV99858189; called by muse, mutect2, varscan2
- BICD2 | c.413A>G p.E138G | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as COSV100794376; called by muse, mutect2, varscan2
- C6orf15 | c.164C>A p.P55H | Missense Mutation (SNP) | VAF 50/154 reads (32%) | SIFT tolerated (0.63); PolyPhen benign (0.035); catalogued as COSV99457332; called by muse, mutect2
- CDK12 | c.884A>G p.Y295C | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.956); catalogued as rs749865286, COSV101420560; called by muse, mutect2, varscan2
- CDX4 | c.172C>A p.H58N | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100999163; called by muse, mutect2, varscan2
- CHD9 | c.6215T>C p.L2072P | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.084); catalogued as COSV99529853; called by muse, mutect2, varscan2
- CISH | c.538C>T p.P180S (on ENST00000348721 / NM_145071.4; = p.P197S on NM_013324.6) | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.041); catalogued as COSV100811806; called by muse, mutect2, varscan2
- COL11A2 | c.3940C>A p.P1314T (on ENST00000341947 / NM_080680.3; = p.P1207T on NM_080679.2) | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.185); catalogued as COSV100554613; called by muse, mutect2, varscan2
- COL7A1 | c.2322G>T p.E774D | Missense Mutation (SNP) | VAF 67/280 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100097900; called by muse, mutect2, varscan2
- CTTNBP2 | c.4427A>G p.K1476R | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV99355002; called by muse, mutect2, varscan2
- DGKK | c.2118A>T p.K706N | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV101053242; called by muse, mutect2, varscan2
- DPY19L3 | c.1778T>A p.L593Q | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100639328, COSV60474736; called by muse, mutect2, varscan2
- EPHA4 | c.2954C>A p.P985H | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.888); catalogued as COSV56034264, COSV99917614; called by muse, mutect2, varscan2
- FAM32A | c.121A>G p.M41V | Missense Mutation (SNP) | VAF 41/150 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0.028); catalogued as COSV99655349; called by muse, mutect2, varscan2
- FGA | c.1186G>A p.D396N | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.518); catalogued as COSV100120805; called by muse, mutect2, varscan2
- FMN2 | c.4534G>T p.D1512Y | Missense Mutation (SNP) | VAF 56/133 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100147037; called by muse, mutect2, varscan2
- FRZB | c.619A>T p.K207* | Nonsense Mutation (SNP) | VAF 32/101 reads (32%) | catalogued as COSV99717586; called by muse, mutect2, varscan2
- GALNT5 | c.1603G>C p.D535H | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99375649; called by muse, mutect2, varscan2
- HIPK3 | c.1135G>A p.A379T | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100306112; called by muse, mutect2, varscan2
- HLA-DMA | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 41/205 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.059); catalogued as rs1477449986, COSV100877689; called by muse, mutect2, varscan2
- HOXB2 | c.905C>A p.P302H | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV100344837; called by muse, mutect2, varscan2
- IGKV2-24 | c.325G>A p.G109R | Missense Mutation (SNP) | VAF 99/312 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs1269755708; called by muse, mutect2, varscan2
- ITGB1BP2 | c.797C>A p.A266E | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.88); PolyPhen benign (0.022); catalogued as COSV99339196; called by muse, mutect2, varscan2
- KIAA0319L | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 43/137 reads (31%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV100357784; called by muse, mutect2, varscan2
- KIAA1586 | c.291C>A p.H97Q | Missense Mutation (SNP) | VAF 50/253 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.605); catalogued as COSV100875401; called by muse, mutect2, varscan2
- KLF11 | c.689C>G p.S230C | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.747); catalogued as COSV100007947; called by muse, mutect2, varscan2
- KRT34 | c.1106A>T p.E369V | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101222736; called by muse, mutect2, varscan2
- LHX3 | c.1117G>T p.G373W (on ENST00000371748 / NM_178138.6; = p.G378W on NM_014564.5) | Missense Mutation (SNP) | VAF 50/168 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100871304; called by muse, mutect2, varscan2
- LRFN1 | c.817G>T p.E273* | Nonsense Mutation (SNP) | VAF 11/49 reads (22%) | catalogued as COSV99953439; called by muse, mutect2, varscan2
- LRRC8A | c.1001T>A p.L334H | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as COSV99396986; called by muse, mutect2, varscan2
- LYST | c.9101T>C p.L3034S | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746297204, COSV101090423; called by muse, mutect2
- NADK | c.1238C>A p.P413H | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.04); catalogued as COSV100411102; called by muse, mutect2
- NEO1 | c.178G>C p.V60L | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as rs764492714, COSV99982918; called by muse, mutect2
- NFATC4 | c.2197G>A p.E733K | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.67); PolyPhen benign (0.02); catalogued as rs755075807, COSV51596936; called by muse, mutect2, varscan2
- NLRP13 | c.796T>G p.F266V | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100738609; called by muse, mutect2, varscan2
- NNT | c.974C>T p.A325V | Missense Mutation (SNP) | VAF 66/202 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99239703; called by muse, mutect2, varscan2
- NPAS4 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 65/177 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.727); catalogued as rs1222029595, COSV60652081; called by muse, mutect2, varscan2
- OR5M10 | c.811T>A p.S271T | Missense Mutation (SNP) | VAF 64/222 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.344); catalogued as COSV101595927; called by muse, mutect2, varscan2
- PGLYRP4 | c.259C>A p.L87M | Missense Mutation (SNP) | VAF 34/55 reads (62%) | SIFT tolerated (0.58); PolyPhen benign (0.163); catalogued as COSV100668542; called by muse, mutect2, varscan2
- PLCH2 | c.2323G>A p.D775N | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs747707446, COSV53943475; called by muse, mutect2, varscan2
- PTPN13 | c.4933T>C p.S1645P (on ENST00000411767 / NM_080683.3; = p.S1626P on NM_006264.3) | Missense Mutation (SNP) | VAF 72/249 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV100365540; called by muse, mutect2, varscan2
- RB1 | c.540-2A>T p.X180_splice | Splice Site (SNP) | VAF 19/33 reads (58%) | catalogued as CS030548, COSV99927106; called by muse, mutect2, varscan2
- RPS3A | c.65T>C p.V22A | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.895); catalogued as COSV99923784; called by muse, mutect2, varscan2
- SDK1 | c.1219G>A p.G407R | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.084); catalogued as rs780085119, COSV67391027; called by muse, mutect2, varscan2
- SEL1L | c.15A>G p.I5M | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.006); catalogued as rs746774740, COSV100378150; called by muse, mutect2, varscan2
- SLC34A3 | c.184G>A p.V62M | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs754789761, COSV100746728; called by muse, mutect2, varscan2
- SLITRK4 | c.1438T>G p.L480V | Missense Mutation (SNP) | VAF 57/220 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100567549; called by muse, mutect2, varscan2
- SNX5 | c.275C>G p.P92R | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100899116; called by muse, mutect2, varscan2
- TANGO6 | c.2932T>G p.L978V | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV99937090; called by muse, mutect2, varscan2
- TUSC3 | c.929A>G p.K310R | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.534); catalogued as COSV101142921; called by muse, mutect2
- TUT7 | c.2511G>T p.Q837H | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV52896727; called by muse, mutect2, varscan2
- UBLCP1 | c.287T>G p.V96G | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.362); catalogued as COSV99707470; called by muse, mutect2, varscan2
- UBP1 | c.54C>G p.D18E | Missense Mutation (SNP) | VAF 64/196 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as COSV99372951; called by muse, mutect2, varscan2
- USP26 | c.2032A>T p.S678C | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100896785; called by muse, mutect2, varscan2
- ZNF264 | c.146T>C p.L49P | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1309835948, COSV54042814; called by muse, mutect2, varscan2
- ZNF582 | c.866G>T p.G289V | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100019015; called by muse, mutect2, varscan2
- ZNF766 | c.1342T>G p.F448V | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as COSV100765492; called by muse, mutect2, varscan2
- PZP | c.1350_1365del p.L450Ffs*24 | Frame Shift Del (DEL) | VAF 28/91 reads (31%) | called by mutect2, pindel, varscan2
- RAPGEF2 | c.1657_1660dup p.G554Dfs*9 | Frame Shift Ins (INS) | VAF 32/131 reads (24%) | called by mutect2, pindel, varscan2
- SCP2 | c.683del p.S228* | Frame Shift Del (DEL) | VAF 19/60 reads (32%) | called by mutect2, pindel, varscan2
- AHNAK2 | c.14928C>T p.D4976= | Silent (SNP) | VAF 26/94 reads (28%) | catalogued as COSV100319177; called by muse, mutect2, varscan2
- ASPG | c.1677G>A p.A559= | Silent (SNP) | VAF 31/121 reads (26%) | catalogued as rs374185145; called by muse, mutect2, varscan2
- AVPR2 | c.285C>T p.P95= | Silent (SNP) | VAF 36/92 reads (39%) | catalogued as rs1557100550, COSV100509492, COSV100509701; called by muse, mutect2, varscan2
- C3orf20 | c.1263C>T p.A421= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as rs766033368, COSV99514659; called by mutect2, varscan2
- C5orf22 | c.654A>G p.P218= | Silent (SNP) | VAF 86/220 reads (39%) | catalogued as rs1291974196, COSV100323693; called by muse, mutect2, varscan2
- CCDC151 | c.1464G>C p.L488= | Silent (SNP) | VAF 32/72 reads (44%) | catalogued as COSV100710668; called by muse, mutect2, varscan2
- CDH26 | c.1233T>C p.P411= | Silent (SNP) | VAF 34/98 reads (35%) | catalogued as COSV99723117; called by muse, mutect2, varscan2
- CRAT | c.330C>T p.Y110= | Silent (SNP) | VAF 50/186 reads (27%) | catalogued as COSV58876751; called by muse, mutect2, varscan2
- EPHA3 | c.1060C>A p.R354= | Silent (SNP) | VAF 52/168 reads (31%) | catalogued as COSV100349371, COSV60727113; called by muse, mutect2, varscan2
- GPR142 | c.564C>T p.T188= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs757229629, COSV100171048; called by muse, mutect2, varscan2
- IRX4 | c.1386C>T p.G462= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as rs1031835435, COSV51472631; called by muse, mutect2, varscan2
- MAGI2 | c.2347A>C p.R783= | Silent (SNP) | VAF 21/90 reads (23%) | catalogued as rs1563221199, COSV100836834; called by muse, mutect2, varscan2
- NBEAL2 | c.7770A>G p.A2590= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as COSV99437901; called by muse, mutect2, varscan2
- OR5D14 | c.717C>T p.A239= | Silent (SNP) | VAF 33/92 reads (36%) | catalogued as rs764256582, COSV100162087, COSV100162417, COSV59455247; called by muse, mutect2, varscan2
- PHC3 | c.1822A>C p.R608= (on ENST00000494943 / NM_001308116.2; = p.R620= on NM_024947.4) | Silent (SNP) | VAF 25/126 reads (20%) | catalogued as COSV101520197; called by muse, mutect2, varscan2
- PRTFDC1 | c.573A>G p.P191= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as rs773607915, COSV100197213; called by muse, mutect2, varscan2
- SLIT2 | c.3378T>C p.D1126= | Silent (SNP) | VAF 10/103 reads (10%) | catalogued as COSV99887825; called by muse, mutect2
- SOWAHA | c.621A>T p.A207= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV101097747; called by muse, mutect2, varscan2
- STK17B | c.345T>G p.G115= | Silent (SNP) | VAF 28/88 reads (32%) | catalogued as COSV99826322; called by muse, mutect2, varscan2
- TNS3 | c.2874T>A p.V958= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV100236598; called by muse, mutect2, varscan2
- UBE4A | c.543C>T p.F181= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV99348681; called by muse, mutect2, varscan2
- ZMYM2 | c.24A>G p.G8= | Silent (SNP) | VAF 37/153 reads (24%) | catalogued as COSV101244161; called by muse, mutect2, varscan2
- ZNF229 | c.408T>C p.D136= | Silent (SNP) | VAF 23/76 reads (30%) | catalogued as COSV99351048; called by muse, mutect2, varscan2
